Somatic mutation profile of tumor specimen 0DOO1K from CCDI case PBCCLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,938 days).
Specimen 0DOO1K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efe2897d-b6e7-41e2-a3fd-eccf34568adc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOOCU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34bcebd-db03-4f89-8b40-b2caac4d3818

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, 3'UTR 3, Intron 2, 3'Flank 1, Nonsense Mutation 1, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 309/532 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs377662947; called by muse, mutect2, varscan2
- CROCC2 | c.4318C>T p.R1440C | Missense Mutation (SNP) | VAF 655/1435 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); catalogued as rs779673405; called by muse, mutect2, varscan2
- LRFN3 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 34/626 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1477863802, COSV55817019, COSV99873408; called by muse, mutect2
- MXRA5 | c.6991G>A p.G2331R | Missense Mutation (SNP) | VAF 294/1510 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs377257766, COSV54239645; called by muse, mutect2, varscan2
- OR51E2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 174/1381 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201184158, COSV67808196; called by muse, mutect2, varscan2
- PPRC1 | c.4466C>G p.S1489C | Missense Mutation (SNP) | VAF 106/1212 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as rs768409015; called by muse, mutect2
- PRKCE | c.2110C>G p.R704G | Missense Mutation (SNP) | VAF 38/1424 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV100078913; called by muse, mutect2
- PTAFR | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 40/1502 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs1190531918; called by muse, mutect2
- SERINC4 | c.280-3C>A | Splice Region (SNP) | VAF 82/800 reads (10%) | catalogued as rs1451020459; called by mutect2, varscan2
- WAC | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 822/1306 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs548298771; called by muse, mutect2, varscan2
- ZNF19 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 458/964 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.043); catalogued as rs1346110420, COSV55508149; called by muse, mutect2
- ADAMTSL3 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 39/1687 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GRAMD2A | c.841T>C p.C281R | Missense Mutation (SNP) | VAF 33/1078 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- MUC16 | c.43470G>T p.Q14490H | Missense Mutation (SNP) | VAF 56/906 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2
- NUTM2G | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 50/1359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD2L1 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 140/670 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- POTEF | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 269/2646 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAB6A | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 46/1786 reads (3%) | called by muse, mutect2
- RCOR3 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 59/1536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TET1 | c.1702A>T p.M568L | Missense Mutation (SNP) | VAF 28/940 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UBR1 | c.2585-1G>T p.X862_splice | Splice Site (SNP) | VAF 52/1454 reads (4%) | called by muse, mutect2
- ZBTB1 | c.541C>G p.Q181E | Missense Mutation (SNP) | VAF 164/982 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- BTBD7 | c.651C>T p.V217= | Silent (SNP) | VAF 275/604 reads (46%) | catalogued as rs142872848; called by muse, mutect2, varscan2
- FAM122B | c.393C>T p.S131= | Silent (SNP) | VAF 45/1548 reads (3%) | called by muse, mutect2
- LLGL2 | c.24G>A p.G8= | Silent (SNP) | VAF 450/750 reads (60%) | catalogued as COSV51401026; called by muse, mutect2, varscan2
- NR5A2 | c.402G>A p.Q134= (on ENST00000367362 / NM_205860.3; = p.Q88= on NM_003822.5) | Silent (SNP) | VAF 92/1662 reads (6%) | catalogued as rs746566364, COSV99370978; called by muse, mutect2
- STAT1 | c.1599C>T p.P533= | Silent (SNP) | VAF 461/1046 reads (44%) | catalogued as rs747857564, COSV100738795; called by muse, mutect2, varscan2
- ZP1 | c.279C>A p.V93= | Silent (SNP) | VAF 305/1044 reads (29%) | called by muse, mutect2, varscan2
- CHCHD7 | c.-17+934G>A | Intron (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- FSHB | c.*41G>A | 3'UTR (SNP) | VAF 96/348 reads (28%) | called by muse, mutect2, varscan2
- KLHL4 | c.*2708C>T | 3'UTR (SNP) | VAF 37/243 reads (15%) | catalogued as rs994125687; called by muse, mutect2, varscan2
- MYEF2 | c.*1822C>G | 3'UTR (SNP) | VAF 102/992 reads (10%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45228138 G>A | 3'Flank (SNP) | VAF 382/933 reads (41%) | catalogued as rs754009678; called by muse, mutect2, varscan2
- SEPTIN3 | c.-68G>T | 5'UTR (SNP) | VAF 22/696 reads (3%) | called by muse, mutect2
- SLC1A5 | c.567-94C>T | Intron (SNP) | VAF 55/1558 reads (4%) | called by muse, mutect2
